TCGA case TCGA-UD-AABY — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Western Australia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a20fb646-2a9e-42ac-a2cc-ff3d6a0625fa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 50 years; Vital status: Dead; Days to death: 843 days (2.3 years).

Diagnoses (3)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,315 days); Year of diagnosis: 1999; Method of diagnosis: Cytology; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 843 days (2.3 years).
   Pathology details: Consistent pathology review: No.
   Treatment given: Treatment type: Pleurodesis, NOS; Timepoint category: Prior to Procurement.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 50.3 years (18,362 days); Days to diagnosis: 47 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 50.7 years (18,519 days); Days to diagnosis: 204 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 47 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 47 days.
- Day 204 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 204 days.
- Days to follow up: 843 days (2.3 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- Serum Mesothelin 0.3 nmol/L [Blood test normal range lower: 0.3; Blood test normal range upper: 2.5].

Exposures
- Exposure type: Asbestos; Age at last exposure: 34; Age at onset: 15; Exposure duration years: 11; Exposure source: Occupational.
- Occupation type: Building Frame and Related Trades Workers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UD-AABY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-UD-AABY-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UD-AABY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UD-AABY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: Yes; Pleurodesis performed 90 days: Yes; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Carpenter/building industry.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Diffuse malignant mesothelioma - NOS; Serum mesothelin prior treatment: 0.3.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Patient was diagnosed 2 years prior to cancer procurement with no surgery until TCGA tumor was resected, therefore this may be considered a progression. Patient was treated with pleurodesis more than 90 days prior to cancer procurement which is acceptable.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 843 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 843 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 47 days.
